Somatic mutation profile of tumor specimen 0DVDUB from CCDI case PBCKTE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 12.5 years (4,568 days).
Specimen 0DVDUB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9486c3f8-52c6-4e8a-9ddf-8315b4c73655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVDUV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e9acba4-ddfc-42b4-b69c-098bf15f49ea

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 7, 5'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYTL5 | c.759C>G p.S253R | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs762969437; called by muse, mutect2, varscan2
- ARHGAP36 | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 98/208 reads (47%) | called by muse, varscan2
- ARHGAP36 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); called by muse, varscan2
- CCDC178 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- HTATSF1 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, varscan2
- LRP10 | c.1066T>C p.C356R | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAPK6 | c.1443A>T p.E481D | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- OPLAH | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SCN8A | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 44/504 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, varscan2
- ZNF775 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFIP2 | c.99+20C>G | Intron (SNP) | VAF 87/164 reads (53%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.-20G>C | 5'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, varscan2
- BAHD1 | c.2053-70A>T | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- COL4A3 | c.2657-68T>C | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- DROSHA | c.2367-73A>C | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 16/92 reads (17%) | catalogued as rs1415560984; called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 18/80 reads (23%) | called by muse, varscan2
- RTN1 | c.1016-32C>T | Intron (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
